Gene-level copy-number profile of tumor specimen TCGA-78-7145-01A from TCGA case TCGA-78-7145, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Middle lobe, lung; AJCC pathologic stage: Stage IV; Age at diagnosis: 52.2 years (19,080 days).
Specimen TCGA-78-7145-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.ac690523-700d-4bdc-b6ca-71bd664435bb.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-78-7145-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/57a4cc1d-c694-4061-b79c-5b4c7e562643

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 145; copy number 1: 505; copy number 2: 12,125; copy number 3: 19,747; copy number 4: 17,838; copy number 5: 5,434; copy number 6: 3,022; copy number 7: 440; copy number 8: 91; copy number 9: 37; copy number 11: 15; copy number 12: 76; copy number 14: 68; copy number 17: 16; copy number 18: 20; copy number 19: 83; copy number 23: 81; copy number 32: 71.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-78-7145-01A-11D-2035-01): tumor purity 0.63, ploidy 3.37, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 145 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:20,942,863–21,298,168, 1 gene (within-gene range 0–1): AC021613.1.
- chr8:20,972,021–21,170,137, 4 genes (within-gene range 0–1): LINC02153, AC103719.1, AC021613.2, AC021613.3.
- chr9:19,705,338–29,826,711, 133 genes (broad region; genes not listed).
- chr9:31,371,611–31,506,615, 3 genes: LINC01243, MTATP6P30, MTCO3P30.
- chr15:80,679,684–80,773,135, 3 genes (within-gene range 0–2): ABHD17C, AC023302.1, AC023302.2.
- chr15:80,841,978–80,842,073, 1 gene: MIR549A.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 998 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:180,154,869–180,204,030, 1 gene, copy number 9: QSOX1.
- chr5:58,198–24,480,057, 392 genes, copy number 7 (broad region; genes not listed).
- chr6:41,026,895–42,500,022, 57 genes, copy number 8–18: UNC5CL, OARD1, TSPO2, APOBEC2, NFYA, AL031778.1, ADCY10P1, TREML1, TREM2, TREML2, TREML3P, TREML4, RNA5SP207, TREML5P, AL391903.2, AL391903.3, TREM1, AL391903.1, RNU6-643P, AL672212.1, NCR2, AL136967.1, AL136967.2, FOXP4-AS1, LINC01276, FOXP4, MIR4641, MDFI, NPM1P51, TFEB, AL035588.1, PGC, AL365205.4, FRS3, AL365205.1, PRICKLE4, TOMM6, USP49, AL365205.3, AL365205.2, AL160163.1, MED20, Y_RNA, BYSL, CCND3, RNU6-761P, AL513008.1, TAF8, AL512274.1, C6orf132, AL096814.1, AL096814.2, GUCA1A, GUCA1B, MRPS10, TRERF1, AL591473.1.
- chr6:43,770,184–44,830,188, 30 genes, copy number 9: VEGFA, AL136131.3, AL157371.2, LINC02537, AL157371.1, AL109615.3, C6orf223, AL109615.2, AL109615.1, AL109615.4, MRPL14, TMEM63B, CAPN11, RN7SL811P, MYMX, SLC29A1, HSP90AB1, SLC35B2, MIR4647, NFKBIE, TMEM151B, AL353588.1, TCTE1, AARS2, SPATS1, CDC5L, MIR4642, AL136140.1, AL136140.2, AL133334.1.
- chr6:44,898,711–44,899,295, 1 gene, copy number 9: NUDT19P4.
- chr6:46,204,729–47,627,263, 22 genes, copy number 8: ACTG1P9, RCAN2, AL359633.1, AL035670.1, CYP39A1, SLC25A27, AL591242.1, TDRD6, PLA2G7, ANKRD66, AL161618.1, MEP1A, ADGRF5, ADGRF5-AS1, ADGRF1, TNFRSF21, B3GNTL1P2, AL451166.1, AL355353.1, CD2AP, Y_RNA, AL358178.1.
- chr6:49,430,360–49,580,166, 5 genes, copy number 9: MMUT, CENPQ, GLYATL3, C6orf141, CYP2AC1P.
- chr8:4,787,332–4,788,584, 1 gene, copy number 8: PAICSP4.
- chr8:9,555,912–10,712,187, 23 genes, copy number 7 (within-gene range 5–7): TNKS, AC103834.1, MIR597, MIR124-1HG, MIR124-1, AC034111.2, AC034111.1, MSRA, AC023385.1, AC079200.1, AC112673.1, AC104964.2, LINCR-0001, PRSS52P, RNU6-729P, AC104964.1, PRSS51, AC104964.3, PRSS55, RP1L1, MIR4286, C8orf74, RNA5SP252.
- chr8:77,399,072–94,262,350, 244 genes, copy number 7–32 (broad region; genes not listed).
- chr8:99,013,266–99,877,580, 1 gene, copy number 19 (within-gene range 4–19): VPS13B.
- chr8:99,340,305–101,076,407, 44 genes, copy number 19: AP004289.2, AP004289.1, Y_RNA, MIR599, MIR875, RN7SL350P, AC018442.1, AC018442.2, AC018442.3, COX6C, AC105328.1, RGS22, SNORD77B, AC021590.1, FBXO43, POLR2K, SPAG1, Y_RNA, AC025647.1, Y_RNA, RNF19A, AP001574.1, AP003472.1, MIR4471, AP003472.2, AP000424.1, AP000424.2, ANKRD46, GAPDHP62, SNX31, AP001205.1, RNU6-1092P, PABPC1, MIR7705, RNU6ATAC41P, Y_RNA, RPS20P23, RNU4-83P, RPS26P6, Metazoa_SRP, AC027373.1, YWHAZ, RN7SL685P, FLJ42969.
- chr8:120,380,761–124,580,648, 76 genes, copy number 8–14 (within-gene range 6–14) (broad region; genes not listed).
- chr8:126,556,323–127,419,050, 1 gene, copy number 12 (within-gene range 3–12): PCAT1.
- chr8:127,072,694–129,683,770, 31 genes, copy number 7–12 (within-gene range 3–12): CASC19, PRNCR1, AC020688.1, AC018714.2, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, AC108925.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, AC100822.1, LINC00824, CCDC26, AC103833.2, AC103833.1, RN7SKP206, AC011257.1.
- chr8:129,839,593–130,017,129, 1 gene, copy number 7 (within-gene range 3–7): CYRIB.
- chr8:129,939,844–132,111,159, 22 genes, copy number 7: AC022973.3, AC131568.1, RNU7-181P, MIR5194, ASAP1, RNU6-1255P, ASAP1-IT2, AC103725.1, AC009682.1, AC139019.1, AC090987.1, ADCY8, AC103726.1, AC103726.2, AC087341.1, AC104257.1, SNORA72, AC060788.1, EFR3A, OC90, AC100868.1, HHLA1.
- chr9:30,388,935–30,575,012, 1 gene, copy number 11 (within-gene range 6–11): LINC01242.
- chr10:37,523,011–38,783,108, 40 genes, copy number 14 (within-gene range 3–14): TACC1P1, MTND1P18, MTRNR2L7, AL132657.1, ZNF248, AL132657.2, ZNF33BP1, TLK2P2, AL135791.1, ZNF37CP, ZNF33CP, ZNF25, ZNF25-DT, Y_RNA, ZNF33A, RNU6-795P, AL161931.1, EIF3LP3, FXYD6P2, ZNF37A, AL117339.4, AL117339.3, AL117339.1, CCNYL4, AL133217.1, AL117339.2, HSD17B7P2, SEPTIN7P9, AL133216.2, RNU6-1118P, CICP9, AL133216.1, ABCD1P2, AL133173.2, PABPC1P12, SLC9B1P3, ACTR3BP5, CHEK2P5, AL133173.1, AL590623.1.
- chr17:51,312,609–51,521,401, 5 genes, copy number 8 (within-gene range 4–8): LINC02071, AC005823.2, AC005823.1, LINC02073, RPL7P48.

Autosomal genes at a single copy (total copy number 1): 505. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
